TCGA case TCGA-AF-2692 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/71a32fca-d48f-4ea3-8df7-69f9dda8fa91

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 54.3 years (19,830 days); Year of diagnosis: 2009; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 412 days (1.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 12; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Recurrent Disease; Days to treatment start: 344 days; Days to treatment end: 384 days (1.1 years); Treatment dose: 87,000 mg; Prescribed dose: 1500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 350 days; Days to treatment end: 385 days (1.1 years); Treatment dose: 5,000 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 418 days (1.1 years); Days to treatment end: 435 days (1.2 years); Treatment dose: 3,500 cGy; Course number: 1; Number of fractions: 14; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 55.2 years (20,157 days); Days to diagnosis: 327 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 396 days (1.1 years); Residual disease: R0; Treatment anatomic sites: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (2 entries)
- Day 327 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 327 days.
- Days to follow up: 412 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 10.6 ng/mL.
- KRAS mutation, nos: Positive; Mutation codon: 12.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 64.4 kg; Height: 170 cm; BMI: 22.3.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AF-2692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.7.
  Slide TCGA-AF-2692-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 1; Percent stromal cells: 5.
  Slide TCGA-AF-2692-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 5.
- Sample TCGA-AF-2692-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AF-2692-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-AF-2692-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.9; Shortest dimension: 0.7.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 10.6; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Xeloda; Therapy regimen: Recurrence.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 412 days; disease-specific survival: no event (censored), 412 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 327 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AF-2692-01A-01D-0819-01): tumor purity 0.74, ploidy 2.76, whole-genome doublings 1.
